Somatic mutation profile of tumor specimen MP2PRT-PASJVA-TMP1-A (aliquot MP2PRT-PASJVA-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PASJVA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,435 days).
Specimen MP2PRT-PASJVA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ae37371-9f8a-45f0-9809-39ff68b3f3ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASJVA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASJVA-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24b09eec-3e28-42fa-90a5-17ad1e909abf

The open-access MAF lists 15 somatic variants for this specimen: 15 protein-altering or splice-affecting.
By variant classification: Missense Mutation 12, In Frame Ins 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.2033dup p.I679Dfs*21 | Frame Shift Ins (INS) | VAF 96/104 reads (92%) | catalogued as rs587781807; ClinVar: pathogenic; called by mutect2, varscan2
- AFF2 | c.3589G>C p.A1197P | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV53996724; called by muse, mutect2, varscan2
- CALCB | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 136/340 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773988089, COSV60834345; called by muse, mutect2, varscan2
- CYP2J2 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 156/180 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779509762, COSV64607112; called by muse, mutect2, varscan2
- GABRG1 | c.1154G>A p.G385E | Missense Mutation (SNP) | VAF 100/192 reads (52%) | SIFT tolerated (1); PolyPhen possibly damaging (0.491); catalogued as COSV99777450; called by muse, mutect2, varscan2
- PPARGC1B | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 63/475 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs149201557; called by muse, mutect2, varscan2
- SDK1 | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 136/283 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs752082365, COSV67354701; called by muse, mutect2, varscan2
- UBE2D3 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.974); catalogued as COSV57661201, COSV57663600; called by muse, varscan2
- WNK1 | c.4222G>C p.V1408L (on ENST00000315939 / NM_018979.4; = p.V1161L on NM_014823.3) | Missense Mutation (SNP) | VAF 25/471 reads (5%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV60043447; called by muse, mutect2
- CFAP65 | c.154C>A p.L52I | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- DCC | c.4257G>T p.V1419= | Splice Region (SNP) | VAF 136/305 reads (45%) | called by muse, mutect2
- EGFR | c.1480A>G p.R494G | Missense Mutation (SNP) | VAF 81/188 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- FLNA | c.5900C>G p.S1967C (on ENST00000369850 / NM_001110556.2; = p.S1959C on NM_001456.3) | Missense Mutation (SNP) | VAF 208/471 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- IGHV4-59 | c.346_347insTCCAAG p.R116delinsIQG | In Frame Ins (INS) | VAF 10/38 reads (26%) | called by mutect2, pindel
- TTN | c.8506C>T p.P2836S (on ENST00000591111; = p.P2790S on NM_003319.4) | Missense Mutation (SNP) | VAF 216/449 reads (48%) | PolyPhen benign (0.066); called by muse, mutect2, varscan2
